Somatic mutation profile of tumor specimen 0DYNNL from CCDI case PBCTCS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.0 years (1,455 days).
Specimen 0DYNNL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65ffead1-490a-4834-9f1e-733c404b86f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYNMI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3dd2b516-c9bb-4430-9f44-0f2e052d1fa5

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD1 | c.134G>C p.R45T | Missense Mutation (SNP) | VAF 196/222 reads (88%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV57757887; called by muse, mutect2, varscan2
- FRZB | c.97G>T p.A33S | Missense Mutation (SNP) | VAF 102/469 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1442023364; called by muse, mutect2, varscan2
- PITRM1 | c.1274T>C p.I425T | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs780100902; called by muse, mutect2, varscan2
- ANKRD17 | c.5231G>A p.G1744E | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DALRD3 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 18/578 reads (3%) | called by muse, mutect2
- DSCAML1 | c.3863G>T p.C1288F (on ENST00000321322; = p.C1228F on NM_020693.4) | Missense Mutation (SNP) | VAF 140/572 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by mutect2, varscan2
- F5 | c.6182G>T p.C2061F | Missense Mutation (SNP) | VAF 94/414 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRMD3 | c.908A>G p.E303G | Missense Mutation (SNP) | VAF 125/405 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT17 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 151/358 reads (42%) | called by muse, mutect2, varscan2
- MARK4 | c.1190C>A p.T397K | Missense Mutation (SNP) | VAF 97/516 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.261); called by mutect2, varscan2
- MYH7B | c.149A>T p.E50V | Missense Mutation (SNP) | VAF 189/717 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- PKHD1 | c.5098A>T p.T1700S | Missense Mutation (SNP) | VAF 200/229 reads (87%) | SIFT tolerated (0.57); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- PRKACG | c.505A>T p.K169* | Nonsense Mutation (SNP) | VAF 101/337 reads (30%) | called by muse, mutect2, varscan2
- RFX7 | c.520G>A p.G174R (on ENST00000559447 / NM_001368074.1; = p.G271R on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 191/221 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CSPG4 | c.3444C>T p.A1148= | Silent (SNP) | VAF 155/183 reads (85%) | catalogued as rs753265519; called by muse, mutect2, varscan2
- FRZB | c.96T>C p.A32= | Silent (SNP) | VAF 104/474 reads (22%) | called by muse, mutect2, varscan2
- NLRP2 | c.1794G>T p.T598= | Silent (SNP) | VAF 66/431 reads (15%) | called by muse, mutect2
